Somatic mutation profile of tumor specimen b10c7b72-1d44-4668-a637-a536b2 (aliquot b10c7b72-1d44-4668-a637-a536b2_D6_1) from CPTAC case 11BR054, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.3 years (30,781 days).
Specimen b10c7b72-1d44-4668-a637-a536b2: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) febd85a2-d22a-4f99-885e-c9781370c07b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4c811274-4185-4b8b-93dd-93dbaf (Blood Derived Normal), aliquot 4c811274-4185-4b8b-93dd-93dbaf_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58ed0385-9223-4415-babf-7d801631c2fa

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Nonsense Mutation 3, 3'UTR 1, RNA 1, Frame Shift Del 1, 5'Flank 1, Splice Site 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA3 | c.1198_1199del p.M400Vfs*106 | Frame Shift Del (DEL) | VAF 36/147 reads (24%) | catalogued as rs1085307641, COSV60521761; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AC011005.1 | c.1001A>G p.N334S | Missense Mutation (SNP) | VAF 90/234 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs953080031; called by muse, mutect2, varscan2
- AP4M1 | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as COSV57994107; called by muse, varscan2
- ARHGEF1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs782168958; called by muse, mutect2, varscan2
- CARD14 | c.2635G>A p.V879M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs764537252; called by mutect2, varscan2
- CTAG2 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as rs1170937730; called by muse, mutect2, varscan2
- DHX58 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV52427457; called by muse, mutect2
- EIF4ENIF1 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV57515112; called by muse, mutect2, varscan2
- LDB2 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 47/111 reads (42%) | catalogued as rs771669555, COSV58763457; called by muse, mutect2, varscan2
- OR4A5 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs142357039; called by muse, mutect2, varscan2
- PPP6R3 | c.615A>T p.E205D | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.38); catalogued as rs147458286; called by muse, mutect2, varscan2
- TBX15 | c.1211G>A p.R404Q (on ENST00000369429 / NM_001330677.2; = p.R298Q on NM_152380.3) | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs202186272, COSV52868227; called by muse, mutect2, varscan2
- TMEM19 | c.244+1G>C p.X82_splice | Splice Site (SNP) | VAF 25/74 reads (34%) | catalogued as COSV56998811; called by muse, mutect2
- CSNK2A1 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 68/184 reads (37%) | called by muse, mutect2, varscan2
- DCTPP1 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FOXO6 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GSE1 | c.-1_3del | Translation Start Site (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- INPP5D | c.1786A>G p.T596A (on ENST00000445964 / NM_001017915.3; = p.T595A on NM_005541.5) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MAML2 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.987); called by muse, mutect2
- MARCHF10 | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MIDN | c.195dup p.V66Sfs*27 | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | called by pindel, varscan2
- NEB | c.11093C>G p.A3698G | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRCAP | c.543C>G p.H181Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRCAP | c.542A>C p.H181P | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC1A7 | c.762T>A p.N254K | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTF2 | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- C9orf50 | c.1125C>T p.A375= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs749311308; called by muse, mutect2, varscan2
- DYSF | c.798T>C p.L266= | Silent (SNP) | VAF 72/204 reads (35%) | called by muse, mutect2, varscan2
- IL4I1 | c.702C>G p.S234= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs138503884, COSV55582249; called by muse, mutect2, varscan2
- MGAT4B | c.1296G>A p.A432= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as rs766971194; called by muse, mutect2, varscan2
- PRKCQ | c.423T>G p.A141= | Silent (SNP) | VAF 41/112 reads (37%) | called by muse, mutect2, varscan2
- PTCD2 | c.63G>T p.L21= | Silent (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- RRP1B | c.1695C>T p.P565= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as rs1458381139, COSV61478830; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501848 G>A | 5'Flank (SNP) | VAF 63/154 reads (41%) | called by muse, mutect2, varscan2
- CD2AP | c.*22T>G | 3'UTR (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.2328C>T | RNA (SNP) | VAF 49/178 reads (28%) | called by muse, mutect2, varscan2
